Gene-level copy-number profile of tumor specimen TCGA-66-2786-01A from TCGA case TCGA-66-2786, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.6 years (25,051 days).
Specimen TCGA-66-2786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c7a5f76e-55f0-4d2e-922b-7060e7820635.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2786-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bcc16e49-4b52-4a2d-872f-b6028bf0c3e7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 15,163; copy number 3: 5,534; copy number 4: 32,119; copy number 5: 5,320; copy number 6: 71; copy number 7: 664; copy number 9: 7; copy number 10: 710; copy number 11: 4; copy number 12: 158; copy number 15: 16; copy number 17: 16; copy number 18: 17; copy number 26: 4; copy number 31: 10; copy number 45: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2786-01A-01D-0844-01): tumor purity 0.57, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 943 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:55,215,624–56,033,361, 23 genes, copy number 9–15 (within-gene range 4–15): RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135.
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr14:99,158,416–101,732,522, 179 genes, copy number 12–26 (broad region; genes not listed).
- chr19:19,749,637–19,979,610, 16 genes, copy number 17 (within-gene range 2–17): AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2, ZNF93, AC007204.1, AC007204.2.
- chr19:20,432,552–20,571,095, 1 gene, copy number 45 (within-gene range 2–45): AC008554.1.
- chr19:20,838,515–21,196,053, 14 genes, copy number 11–31: AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1, ZNF430, AC008739.3, VN1R80P, ZNF714, RNA5SP469, VN1R81P, ZNF431, RPL7AP10, VN1R82P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
